Somatic mutation profile of tumor specimen 0DUETQ from CCDI case PBCLAC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.6 years (4,220 days).
Specimen 0DUETQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fea2193-53b2-41cd-8c9c-7246f74e49bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUETK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ecf92a2-8b47-44df-9fa0-7dacb41c357a

The open-access MAF lists 28 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Del 2, 3'UTR 2, 5'UTR 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 578/1350 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- APOA4 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 219/1853 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs139762470; called by muse, mutect2, varscan2
- ARID2 | c.940del p.R314Vfs*14 | Frame Shift Del (DEL) | VAF 479/1164 reads (41%) | catalogued as COSV57595631, COSV57607050; called by mutect2, pindel, varscan2
- DNAH9 | c.11368G>A p.V3790M | Missense Mutation (SNP) | VAF 227/1004 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs139641473, COSV52344506; called by muse, mutect2, varscan2
- EIF4E | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 120/977 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs772918368, COSV99794595; called by muse, mutect2, varscan2
- ERVV-2 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 198/668 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.903); catalogued as rs755649363; called by muse, mutect2, varscan2
- GNL2 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 207/1439 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs368568971; called by muse, mutect2, varscan2
- MUSK | c.2145C>G p.Y715* | Nonsense Mutation (SNP) | VAF 125/1852 reads (7%) | catalogued as COSV51889146; called by muse, mutect2
- OR11A1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 465/1230 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs756409417, COSV101010668; called by muse, mutect2, varscan2
- HMGN3 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 402/1015 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.9927C>A p.S3309R | Missense Mutation (SNP) | VAF 65/2242 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- PCNX2 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 393/993 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PDE7A | c.784C>G p.P262A (on ENST00000401827 / NM_001242318.3; = p.P236A on NM_002603.4) | Missense Mutation (SNP) | VAF 54/1596 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.124); called by muse, mutect2
- RNF130 | c.332del p.G111Efs*20 | Frame Shift Del (DEL) | VAF 250/1092 reads (23%) | called by mutect2, pindel, varscan2
- XAB2 | c.1750C>G p.L584V | Missense Mutation (SNP) | VAF 180/1458 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.348); called by muse, varscan2
- ARHGEF4 | c.519C>T p.H173= | Silent (SNP) | VAF 216/817 reads (26%) | called by muse, mutect2, varscan2
- BIRC5 | c.213C>T p.D71= | Silent (SNP) | VAF 76/980 reads (8%) | catalogued as rs772996209; called by muse, mutect2
- HEXA | c.1011C>T p.D337= | Silent (SNP) | VAF 371/891 reads (42%) | catalogued as rs1175300517; called by muse, mutect2, varscan2
- MYO15A | c.9180C>T p.I3060= | Silent (SNP) | VAF 322/1542 reads (21%) | catalogued as rs968105343, COSV52762349; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPM1F | c.1041G>A p.A347= | Silent (SNP) | VAF 590/1317 reads (45%) | catalogued as rs762997310; called by muse, mutect2, varscan2
- PTBP2 | c.57C>T p.G19= (on ENST00000426398 / NM_001300986.2; = p.G11= on NM_021190.4) | Silent (SNP) | VAF 429/948 reads (45%) | catalogued as rs751892440; called by muse, mutect2, varscan2
- SEZ6L | c.2907C>T p.S969= | Silent (SNP) | VAF 534/1187 reads (45%) | catalogued as COSV50691294; called by muse, mutect2, varscan2
- IGDCC4 | c.-60C>G | 5'UTR (SNP) | VAF 56/107 reads (52%) | catalogued as rs923093259; called by muse, mutect2, varscan2
- MTDH | c.*24T>A | 3'UTR (SNP) | VAF 40/1156 reads (3%) | called by muse, mutect2
- PATL2 | c.1464-32T>G | Intron (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- RASAL3 | c.2829-88C>T | Intron (SNP) | VAF 71/126 reads (56%) | called by muse, mutect2, varscan2
- ZHX2 | c.-47del | 5'UTR (DEL) | VAF 410/801 reads (51%) | called by mutect2, pindel, varscan2
- ZNF605 | c.*17G>A | 3'UTR (SNP) | VAF 128/284 reads (45%) | catalogued as rs538691984; called by muse, mutect2, varscan2
